Somatic mutation profile of tumor specimen ALCH-B4F1-TTP1-A (aliquot ALCH-B4F1-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4F1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.7 years (28,389 days).
Specimen ALCH-B4F1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b912a45-dc33-42be-89b9-86311ac755ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4F1-NB1-A (Blood Derived Normal), aliquot ALCH-B4F1-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/961beef9-0485-43f0-b1c8-3967843255e9

The open-access MAF lists 129 somatic variants for this specimen: 82 protein-altering or splice-affecting, 30 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 30, RNA 5, Intron 5, Nonsense Mutation 4, 3'Flank 3, Splice Site 3, 3'UTR 3, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.905G>C p.R302P (on ENST00000506720 / NM_001322402.2; = p.R234P on NM_015236.6) | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72266433; called by muse, mutect2
- AL121899.2 | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as rs868202762, COSV101198422; called by muse, mutect2, varscan2
- AOC3 | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV53826840; called by muse, mutect2
- ATP1B4 | c.897C>G p.Y299* (on ENST00000218008 / NM_001142447.3; = p.Y295* on NM_012069.5) | Nonsense Mutation (SNP) | VAF 23/147 reads (16%) | catalogued as COSV54311543; called by muse, mutect2, varscan2
- CACNB2 | c.1607C>A p.A536D (on ENST00000324631 / NM_201596.3; = p.A481D on NM_000724.4) | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.164); catalogued as COSV56628482, COSV99994686; called by muse, mutect2
- CBLN1 | c.376A>T p.T126S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.781); catalogued as COSV99535700; called by muse, mutect2
- CDH18 | c.2176G>T p.D726Y | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99932413, COSV99935122; called by muse, mutect2
- COL11A1 | c.3025-1G>C p.X1009_splice | Splice Site (SNP) | VAF 15/185 reads (8%) | catalogued as COSV62195317; called by muse, mutect2
- CSMD3 | c.3379G>A p.G1127S (on ENST00000297405 / NM_001363185.1; = p.G1023S on NM_052900.3) | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV52105540; called by muse, mutect2
- FAT2 | c.2767C>A p.P923T | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55821784; called by muse, mutect2
- FMN2 | c.4699C>A p.Q1567K | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV60428057; called by muse, mutect2
- FREM3 | c.4813C>A p.L1605M | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.401); catalogued as rs1307783674, COSV61681159; called by muse, mutect2, varscan2
- GRIN2A | c.3668C>A p.T1223N | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770966136, COSV58027993; called by muse, mutect2, varscan2
- IGDCC3 | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100030838; called by muse, mutect2
- IGSF10 | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56786770; called by muse, mutect2
- KRT6C | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 36/516 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.199); catalogued as rs1265421998; called by muse, mutect2
- MYO7B | c.3857G>A p.R1286Q | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375117051; called by muse, mutect2
- OR10Q1 | c.718C>A p.R240S | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV57471669; called by muse, mutect2, varscan2
- OR2T33 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 40/700 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs767161689; called by muse, mutect2
- OR2T4 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV63545190; called by muse, mutect2
- OR4A16 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); catalogued as rs139771656; called by muse, mutect2, varscan2
- PCDH15 | c.4885G>T p.E1629* | Nonsense Mutation (SNP) | VAF 51/787 reads (6%) | catalogued as COSV57256634; called by muse, mutect2
- PTPN7 | c.349C>A p.P117T (on ENST00000495688; = p.P156T on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV58315450; called by muse, mutect2
- RAD54B | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs925899837; called by muse, mutect2
- RIMS2 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.34); catalogued as rs1405112598; called by muse, mutect2
- RTL9 | c.1671G>C p.M557I | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV71826461; called by muse, mutect2, varscan2
- SFPQ | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.028); catalogued as rs1423053254; called by muse, mutect2, varscan2
- UMODL1 | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.092); catalogued as rs764083380; called by muse, mutect2
- USH2A | c.1829A>T p.H610L | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM030086; called by muse, mutect2
- WDFY4 | c.8147G>A p.G2716E | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55440584; called by muse, mutect2, varscan2
- AGAP6 | c.539A>T p.K180M (on ENST00000374056 / NM_001365867.1; = p.K203M on NM_001077665.2) | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ASRGL1 | c.233A>T p.D78V | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BAIAP2 | c.343dup p.Y115Lfs*12 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- C19orf12 | c.24-8C>T | Splice Region (SNP) | VAF 23/401 reads (6%) | called by muse, mutect2
- CACNA2D1 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CCT3 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CCT4 | c.1286A>C p.E429A | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CENPB | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- COL11A2 | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CUL9 | c.3130C>A p.L1044M | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DCUN1D4 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DLX6 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- FAT2 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- FCN1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- GABRA4 | c.520A>G p.M174V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GAK | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HMCN1 | c.4070-2A>T p.X1357_splice | Splice Site (SNP) | VAF 17/305 reads (6%) | called by muse, mutect2
- INTS3 | c.2267G>T p.S756I | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2
- ITGA7 | c.1829A>G p.Q610R (on ENST00000555728; = p.Q566R on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2
- KRTAP10-11 | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- LIX1L | c.914C>A p.A305D | Missense Mutation (SNP) | VAF 26/497 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- LRP4 | c.3471G>T p.M1157I | Missense Mutation (SNP) | VAF 32/383 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.055); called by muse, mutect2
- MRC1 | c.2896G>T p.E966* | Nonsense Mutation (SNP) | VAF 39/634 reads (6%) | called by muse, mutect2
- NAV2 | c.1881G>C p.Q627H (on ENST00000396087 / NM_001244963.2; = p.Q604H on NM_145117.5) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.423); called by muse, mutect2
- NCOA1 | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- NCOA1 | c.3338A>G p.Q1113R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2
- NPR3 | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- NUTM1 | c.950A>T p.D317V | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- OAZ1 | c.658A>G p.R220G | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OCA2 | c.1117A>G p.R373G | Missense Mutation (SNP) | VAF 38/573 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR2AE1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5M3 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- OR6Y1 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- OVCH1 | c.1168G>T p.V390F | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- PDE3B | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.946); called by muse, mutect2
- PTPRN2 | c.1441T>A p.S481T | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RASA2 | c.2056C>G p.Q686E | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMS2 | c.1121C>A p.A374E (on ENST00000666250 / NM_001348490.2; = p.A182E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- RYR2 | c.9108G>T p.L3036F | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SIRPB1 | c.947T>A p.L316Q | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- SLC27A1 | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SPRED3 | c.979C>A p.R327S | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2
- SYNJ1 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- TATDN2 | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 41/520 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- TBX2 | c.1121C>A p.A374E | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- TBX3 | c.1201G>T p.E401* (on ENST00000257566 / NM_016569.4; = p.E381* on NM_005996.4) | Nonsense Mutation (SNP) | VAF 18/253 reads (7%) | called by muse, mutect2
- TDRD15 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2
- TPX2 | c.1408G>T p.V470F | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UNC45A | c.1596-1G>T p.X532_splice | Splice Site (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- UNC79 | c.6245T>A p.L2082Q (on ENST00000393151 / NM_001346218.2; = p.L1905Q on NM_020818.5) | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- VWF | c.3652G>T p.D1218Y | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF132 | c.1961C>A p.P654H | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASPM | c.3303G>A p.R1101= | Silent (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- ATP4A | c.2541A>T p.P847= | Silent (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- B3GAT1 | c.213C>T p.Y71= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV56995051; called by muse, mutect2, varscan2
- CACNA2D1 | c.234G>T p.L78= | Silent (SNP) | VAF 29/447 reads (6%) | called by muse, mutect2
- DOCK2 | c.5490G>T p.L1830= | Silent (SNP) | VAF 35/283 reads (12%) | called by muse, mutect2, varscan2
- GABRB1 | c.1194C>T p.D398= | Silent (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- H1-3 | c.381C>G p.A127= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- IGKV1-17 | c.99G>T p.L33= | Silent (SNP) | VAF 48/652 reads (7%) | called by muse, mutect2
- ITGBL1 | c.819G>A p.E273= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs1457138511; called by muse, mutect2
- KCNB1 | c.1164C>A p.L388= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100870606; called by muse, mutect2, varscan2
- LAMA1 | c.5985G>A p.L1995= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs1273905307; called by muse, mutect2
- LCT | c.2919C>A p.A973= | Silent (SNP) | VAF 19/209 reads (9%) | called by muse, mutect2
- LIX1L | c.915C>A p.A305= | Silent (SNP) | VAF 24/497 reads (5%) | called by muse, mutect2
- OR4D6 | c.246G>T p.L82= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- PARP14 | c.4038C>T p.A1346= | Silent (SNP) | VAF 24/364 reads (7%) | called by muse, mutect2
- PCDHA9 | c.1329G>A p.V443= | Silent (SNP) | VAF 26/212 reads (12%) | catalogued as rs781900935; called by muse, mutect2, varscan2
- PCDHA9 | c.1755G>A p.V585= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- PCDHGA4 | c.2307G>T p.S769= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as rs1263721447, COSV53990265; called by muse, mutect2
- PYGB | c.1251G>T p.A417= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- RELN | c.1284T>G p.P428= | Silent (SNP) | VAF 19/426 reads (4%) | called by muse, mutect2
- SIRPB1 | c.948G>A p.L316= | Silent (SNP) | VAF 19/252 reads (8%) | called by muse, mutect2
- SLC35D3 | c.1017G>A p.G339= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- SNX17 | c.876G>T p.A292= | Silent (SNP) | VAF 36/394 reads (9%) | called by muse, mutect2
- SOS1 | c.159G>A p.L53= | Silent (SNP) | VAF 23/353 reads (7%) | called by muse, mutect2
- SPAM1 | c.804G>A p.Q268= | Silent (SNP) | VAF 10/135 reads (7%) | catalogued as COSV56145430; called by muse, mutect2
- STYXL2 | c.2181T>A p.I727= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- TNN | c.282G>C p.T94= | Silent (SNP) | VAF 30/286 reads (10%) | catalogued as COSV53424316; called by muse, mutect2
- ZFY | c.411G>T p.T137= | Silent (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- ZNF503 | c.882G>T p.V294= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV65307179; called by muse, mutect2
- ZP1 | c.1800A>G p.R600= | Silent (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2
- AC016582.1 | chr19:37824488 T>C | 3'Flank (SNP) | VAF 18/276 reads (7%) | called by muse, mutect2
- AC093791.1 | n.443C>T | RNA (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- AC136759.1 | n.1242A>T | RNA (SNP) | VAF 31/417 reads (7%) | called by muse, mutect2
- AHSA2P | n.1596G>A | RNA (SNP) | VAF 22/289 reads (8%) | called by muse, mutect2
- ALX4 | c.*14C>T | 3'UTR (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- BTNL2 | chr6:32394002 A>T | 3'Flank (SNP) | VAF 32/284 reads (11%) | called by muse, mutect2, varscan2
- CEP41 | c.*1874G>T | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- DACH1 | c.*48C>A | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- DCX | c.-22-578G>T | Intron (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
- FAAP20 | chr1:2185355 G>T | 3'Flank (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- HSP90AB3P | n.913A>G | RNA (SNP) | VAF 8/87 reads (9%) | catalogued as rs545453522; called by muse, mutect2
- MIR1283-2 | n.29G>C | RNA (SNP) | VAF 17/207 reads (8%) | called by muse, mutect2
- NPHP1 | c.1249-50C>T | Intron (SNP) | VAF 14/199 reads (7%) | catalogued as rs1308035009; called by muse, mutect2
- ORC6 | c.562+45C>A | Intron (SNP) | VAF 13/248 reads (5%) | called by muse, mutect2
- VRK1 | c.483+46A>G | Intron (SNP) | VAF 14/127 reads (11%) | catalogued as rs373737505; called by muse, mutect2, varscan2
- WIPI2 | c.576+11T>A | Intron (SNP) | VAF 11/166 reads (7%) | called by muse, mutect2
- ZPLD1 | c.-157G>A | 5'UTR (SNP) | VAF 13/258 reads (5%) | catalogued as COSV60352950; called by muse, mutect2
